Gene-level copy-number profile of specimen HCM-CSHL-0159-C18-85B from HCMI case HCM-CSHL-0159-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: GB; Age at diagnosis: 61.9 years (22,623 days).
Specimen HCM-CSHL-0159-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cf35639d-24bd-46f7-906a-39b66e48b078.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0159-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/20972614-6aa9-487a-b770-18472c2b973c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 589; copy number 2: 34,134; copy number 3: 19,978; copy number 4: 4,059; copy number 5: 140; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–3): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr15:21,293,653–21,325,241, 3 genes (within-gene range 0–5): AC068446.1, AC068446.2, RNU6-1235P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 141 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:21,980,277–21,981,245, 1 gene, copy number 7: OR11J6P.
- chr16:46,469,341–46,575,094, 4 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr20:61,953,469–64,327,972, 136 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 77. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
